Surgical pathology report (de-identified scan), TCGA case TCGA-WE-AAA4, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site  Norfolk and Norwich Hospital, specimen TCGA-WE-AAA4-06A (Metastatic).

ADDRESS FOR REPORT: PLASTICS

Copy To: Dr

Consultant Histopathologist,

HISTOPATHOLOGY REPORT

LAB No:

CASE HISTORY:

1. Raised nodule at scar site for previous MM (nodular MM 5mm depth, high mitotic index, positive SLNB) - ?melanoma recurrence. 2 & 3. 2 new dark spots adjacent to left groin scar for previous L node dissection. 2. Superior, 3. Inferior. ?intransit metastases.

MACROSCOPIC:

1. Biopsy left leg – partially ? necrotic 4mm punch biopsy.
2. Left groin superior – 3mm cream punch biopsy with a 2mm uniformly pigmented macule.
3. Left groin inferior – 3.5mm tan punch biopsy with a 3mm bluey pigmented lesion

Two slides received from
team) labelled

for review (at request of melanoma

MICROSCOPY:

1. I agree with the diagnosis of malignant melanoma deposit in skin.
2. I agree with the diagnosis of no evidence of malignant melanoma in this skin biopsy.

DIAGNOSIS:

1. SKIN, LEFT LEG: DEPOSIT OF MALIGNANT MELANOMA
2. SKIN, LEFT GROIN SUPERIOR: NO EVIDENCE OF MALIGNANT MELANOMA

REPORTED BY:

Dr.

Consultant Histopathologist.

REPORT DATE:

ICD O-3

Melanoma NOS 8720/3
Site: Skin @ leg C44.7
4/28/14

Per TSS, in-transit met.

Source: NCI Genomic Data Commons file 2b482bef-2ae8-45f5-9eac-9e89f000fbf6 (TCGA-WE-AAA4.F35E0D94-9073-4C6D-8F2C-C30A1756742B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).